Surgical pathology report (de-identified scan), CDDP_EAGLE case CDDP-ABJI, project CDDP_EAGLE-1 (CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2)), specimen CDDP-ABJI-TTP1-A (Primary Tumor).

Specimen(s) Received

Lung, HISTOLOGIC EXAMINATION – SURGICAL SPECIMEN

Clinical Information

Gross Examination

Left lower lobectomy: lobe of lung weighing 100 gm and measuring 14 cm in greatest diameter.

In the periphery of the apical-posterior segment there is a subpleural sclerosing neoplasm measuring 1.9 cm. The remainder of the parenchyma is free of lesions.

- A) tumor (70% alcohol fixation)
- B) bronchial margin
- C) serial sections of bronchus with peribronchial lymph nodes
- D) residual parenchyma

Diagnosis

A) Well-differentiated adenocarcinoma (G1) of the type that arises in or is associated with sclerotic/anthracotic scarring in the lung, with bronchioloalveolar colonization of the perilesional air spaces.

The tumor extends to and retracts the visceral pleura but does not perforate it.

B) Bronchial margin uninvolved.

C) Anthracosis and reactive hyperplasia involving 3 hilar lymph nodes isolated. Bronchial airways appear normal.

D) Emphysema, centroacinar type.

SNOMED

T-28000 M-81403 T-C4000 M-72000

TNM

T1 N0 MX G1

1 of 1

Original

ICD-0-3

adenocarcinoma, NOS 8140/3

Site: ⊕ lung, lower lobe C34.3

ICD-10

C34.32

lw
2/9/16

ICD-10 Discrepancy		

Source: NCI Genomic Data Commons file df51a79b-52a7-4b85-a900-57dd5b15512c (CDDP-ABJI-TTP1.123302C9-F2D3-4399-B66A-D1A062A68432.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).